Surgical pathology report (de-identified scan), TCGA case TCGA-06-0167, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0167-01A (Primary Tumor).

[page 1 of 2]
Patient Name.

MRN: 4

Sex: Male Room/Bed:

PATH.NO:

NAME:

MED. REC. NO:

SURGERY DATE:

RECEIVE DATE:

PATIENT PHONE NO.

PHYSICIAN:

COPY TO:

UPDATED REPORT - SEE ADDENDUM DIAGNOSIS, ADDENDUM REPORT

PATHOLOGICAL DIAGNOSIS:

- A. BRAIN, LEFT TEMPORAL, FROZEN SECTION TISSUE: GLIOBLASTOMA
MULTIFORME.
- B. BRAIN, LEFT TEMPORAL, EXCISION: GLIOBLASTOMA MULTIFORME.

SEE MICROSCOPIC.

ADDENDUM DIAGNOSIS:

MIB-1 PROLIFERATION INDEX: 9%

Operation/Specimen: UPDATED REPORT - Brain, left temporal.

Clinical History and Pre-Op Dx: year old man with left temporal,
enhancing tumor, C/W glioblastoma multiforme.

GROSS PATHOLOGY:

- A. Received fresh, two fragments, 1.5 cm across in aggregate. Soft,
tannish-brown, focally hemorrhagic. In total #1-4.

INTRAOPERATIVE CONSULTATION: Brain, left temporal, smears: Glioma
(C/W high histological grade).

- B. Received fresh, one fragment, 3.5 x 2.5 x 1.7 cm. Brain tissue,
focally hemorrhagic and necrotic. Serially sectioned, in
total #5-9.

MICROSCOPIC: A. Portions of cerebrum extensively effaced and focally
infiltrated by a glial neoplastic proliferation. The neoplastic cells
have round nuclei disposed in a fibrillary background. There is
moderate degree of pleomorphism, mitotic figures are found without
difficulty, microvascular cellular proliferation is ubiquitous, and
there are focal areas of necrosis, some with pseudopallisading.

B. Portions of cerebrum containing a neoplasm similar to that one
described for part A. The bulk of the tissue in this specimen is solid
neoplasm, with extensive areas of necrosis.

ADDENDUM REPORT

[page 2 of 2]
Patient Name

MRN:

Sex: M.

Room/Bed:

IMMUNOHISTOCHEMISTRY: Immunoperoxidase methods for GFAP and MIB-1 were performed on sections from block 1. The GFAP demonstrates glial fibrillogenesis by neoplastic cells. With the MIB-1, a proliferation index of 9% is determined in the more active areas.

TISSUE COMMITTEE CODE:
BILLING CODES:

TISSUE COMMITTEE CODE:
BILLING CODES:

Source: NCI Genomic Data Commons file 69709b88-c407-4272-9a5c-d2f492b4dc87 (TCGA-06-0167.AA18AAA2-30E3-41F8-9CCC-2250A588DD30.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).